Surgical pathology report (de-identified scan), TCGA case TCGA-56-8201, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8201-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

* Final Report *

Result type: Surgical Pathology Report
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

*** Final Report ***

Clinical History

Right upper lobe lung cancer

Specimen

- #1 R4 lymph node for frozen
- #2 Level 7 lymph node for frozen
- #3 L4 lymph node for frozen
- #4 R2 lymph node for frozen
- #5 R4 lymph node #2 for frozen
- #6 Level 10 lymph node for perm
- #7 Level 11 lymph node for perm
- #8 Right lung upper lobe, short single stitch superior margin, long double stitch posterior margin, freeze bronchial and superior margins
- #9 5th posterior rib for perm
- #10 R4 lymph node
- #11 R2 lymph node
- #12 Level 7 lymph node
- #13 Right lower lobe nodule
- #14 New posterior soft tissue margin, short stitch superior margin, long stitch posterior margin
- #15 New soft tissue posterior margin

Gross Examination

- #1 Received fresh labeled R4 lymph node are fragments of yellow-gray material in aggregate, 0.6 x 0.5 x 0.3 cm. Completely submitted as a single frozen section.
- #2 Received fresh labeled level 7 lymph node are fragments of yellow to black material in aggregate, 0.7 x 0.6 x 0.3 cm. Completely submitted as a single frozen section.
- #3 Received fresh labeled L4 lymph node are fragments of yellow to gray material, in aggregate 0.6 x 0.5 x 0.3 cm. Completely submitted as a single frozen section.
- #4 Received fresh labeled R2 lymph node are fragments of yellow to black material in aggregate 0.7 x 0.5 x 0.3 cm. Completely submitted as a single frozen section.

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
Surgical Pathology Report

* Final Report *

#5 Received fresh labeled R4 lymph node #2 are fragments of yellow to black material in aggregate 0.6 x 0.5 x 0.3 cm. Completely submitted as a single frozen section.

#6 Labeled level 10 lymph node is a 1.0 x 1.0 x 0.3 cm aggregate of black-gray lymphoid tissue, entirely submitted in one cassette.

#7 Labeled level 11 lymph node are two fragments of black-gray lymphoid tissue, 1.0 x 1.0 x 0.3 cm in aggregate. Completely submitted in one cassette.

#8 Received fresh for Frozen Section, labeled right upper lobe, short single stitch superior margin, long double stitch posterior margin, freeze bronchial and superior margins, is an 18.3 cm (superior to inferior) x 12.5 cm (anterior to posterior) x 6.5 cm (medial to lateral) en bloc right upper lobectomy/chest wall resection with three ribs. The specimen is oriented as stated above. Within the superior aspect of the lung is a 4.9 x 4.7 x 4.5 cm infiltrative white tan, firm mass which grossly invades through the pleura into the adherent medial aspect of the chest wall. It grossly comes to within less than 0.1 cm of the superior soft tissue margin, is approximately 0.7 cm from the inferior soft tissue margin, is 0.3 cm from the anterior soft tissue/rib margin, approximately 3.5 cm from the posterior soft tissue/rib margin and 0.7 cm from the lateral soft tissue margin. The bronchial margin and superior soft tissue margin at the suture are each submitted for Frozen Section. After decalcification, the mass grossly appears to invade into the bone of the two superior-most ribs. The inferior-most rib grossly appears free of tumor. The bronchial and vascular margins are at least 3.5 cm from the mass. The remainder of the lung is composed of dark red, spongy parenchyma without additional mass lesions. Representative fresh tumor and normal lung are procured for the Genome Atlas Tissue Project. Block summary: "A", vascular margin, tangential; "B", lobar lymph nodes; "C,D", lung mass with respect to chest wall superior soft tissue margin, perpendicular; "E", anterior chest wall soft tissue margin, tangential; "F", posterior soft tissue margin, tangential; "G", inferior soft tissue margin, tangential; "H", lateral soft tissue margin, tangential; "I,J", mass with respect to uninvolved lung parenchyma; "K", normal lung; "L", anterior rib margins; "M", posterior rib margins; "N", two superior-most ribs with tumor; "O", inferior-most rib with respect to tumor. "L"- "O" are following decalcification.

#9 Labeled 5th posterior rib is a 2.4 x 2.0 x 1.0 cm aggregate of multiple fragments of pink-tan bony tissue. Representative (approximately 50%) of the tissue is submitted in one cassette.

#10 Labeled 4R lymph node is a 3.0 x 1.6 x 1.4 cm aggregate of adipose tissue and black-gray lymphoid tissue. It is entirely submitted in two: "A", "B".

#11 Labeled R2 lymph node is a 2.0 x 1.5 x 0.4 cm aggregate of three fragments of black-gray lymphoid tissue, entirely submitted in one cassette.

#12 Labeled level 7 lymph node is a 2.4 x 1.6 x 0.8 cm aggregate of

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Surgical Pathology Report

* Final Report *

black-gray lymphoid tissue and adipose tissue. It is entirely submitted as six fragments in one cassette.

#13 Labeled right lower lobe nodule is a 0.7 x 0.6 x 0.2 cm firm, white, focally calcified nodule. It is sectioned and entirely submitted as four sections in one cassette following decalcification. [REDACTED]

#14 Labeled new posterior soft tissue margin, short stitch marked superior margin, long stitch marks posterior margin, is a 3.3 cm long x 1.5 cm in diameter segment of rib with scant attached adipose tissue. It is oriented as stated above and is also received with blue ink at the posterior margin. The posterior margin is entirely submitted and sectioning through the rib demonstrates grossly unremarkable bone. Two sections are submitted in two: "A,B", following decalcification. Block summary: "A", posterior margin, tangential; "B", uninvolved cross section of rib.

#15 Labeled new soft tissue margin, per requisition new soft tissue posterior margin, is a 1.8 x 1.4 x 0.8 cm portion of red brown soft tissue. There is a suture on one surface. The surface is inked black. It is grossly unremarkable on sectioning. It is entirely sequentially submitted as six perpendicular section in "A,B". [REDACTED]

Frozen Section Diagnosis

#1 R4 LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY. [REDACTED]

#2 LEVEL 7 LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY. [REDACTED]

#3 L4 LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY. [REDACTED]

#4 R2 LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY. [REDACTED]

#5 R4 #2 LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY. [REDACTED]

#8 RIGHT LUNG, UPPER LOBE, LOBECTOMY AND CHEST WALL RESECTION (2 FS):
BRONCHIAL

MARGIN NEGATIVE FOR CARCINOMA. CARCINOMA INVADES LESS THAN 0.1 CM FROM
SUPERIOR
SOFT TISSUE MARGIN. [REDACTED]

Microscopic Examination

#1-#15 Microscopic examination performed.

Final Diagnosis

- #1 R4 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
- #2 LEVEL 7 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
- #3 L4 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
- #4 R2 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
- #5 R4 LYMPH NODE #2 BIOPSY: NEGATIVE FOR MALIGNANCY.

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Surgical Pathology Report

* Final Report *

- #6 LEVEL 10 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
#7 LEVEL 11 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
#8 RIGHT LUNG, UPPER LOBE, LOBECTOMY, INCLUDING PARTIAL CHEST WALL RESECTION:
POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
TUMOR SIZE: 4.9 X 4.7 X 4.5 CM.
PROXIMAL BRONCHIAL RESECTION MARGIN STATUS: NEGATIVE FOR CARCINOMA.
SOFT TISSUE (CHEST WALL AND RIB) MARGIN STATUS: CARCINOMA INVADES
LESS THAN 0.1 CM FROM SUPERIOR CHEST WALL SOFT TISSUE SURGICAL MARGIN.
OTHER MARGINS, NEGATIVE FOR CARCINOMA.
PARIETAL PLEURAL SURFACE STATUS: CARCINOMA INVADES THROUGH VISCERAL AND
PLEURA INTO CHEST WALL SKELETAL MUSCLE AND INTO RIB BONE.
LYMPHOVASCULAR SPACE STATUS: NEGATIVE FOR LYMPHOVASCULAR SPACE
INVASION.
LYMPH NODE STATUS: LOBAR LYMPH NODES, NEGATIVE FOR CARCINOMA.
PATHOLOGIC STAGE (TNM CLASSIFICATION): pT3 pN0 PL3.
#9 5TH POSTERIOR RIB: NEGATIVE FOR MALIGNANCY.
#10 R4 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
#11 R2 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
#12 LEVEL 7 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.
#13 RIGHT LOWER LOBE NODULE: BENIGN FIBROTIC NODULE.
#14 NEW POSTERIOR SOFT TISSUE MARGIN: BONE AND SKELETAL MUSCLE, NEGATIVE FOR
MALIGNANCY.
#15 NEW POSTERIOR SOFT TISSUE MARGIN: SKELETAL MUSCLE, NEGATIVE FOR MALIGNANCY.

Signature Line

Signed by: [REDACTED]
ELECTRONIC SIGNATURE

Ordering Provider

Ordering Physician: [REDACTED]

Printed by: [REDACTED]
Printed on: [REDACTED]

Source: NCI Genomic Data Commons file 1b5fae3a-2ea4-4eab-9829-f26254383039 (TCGA-56-8201.8990E058-ECF1-4387-8CB5-96EBEF082CAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).